Surgical pathology report (de-identified scan), TCGA case TCGA-86-8673, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8673-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

	OpenClinica ID	Excision date	Gross Description
			Lung lobe of 23 x 12 cm. Subleural there is a grey-yellow coloured tumour of 8 cm in size, with focal necrosis.

[page 2 of 3]
Microscopic Description	Diagnosis Details	Comments
Bronchioalveolar cancer. Four bronchopulmonary lymph nodes - follicular hyperplasia, antracosis. Aortic window node - antracosis. One bifurcational lymph node - antracosis.	Tumor Features: Unknown, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:	The type of bronchioloalveolar carcinoma (mucinous or nonmucinous) is not defined in the original pathology report.

[page 3 of 3]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 8 x 0 x 0 cm

Histologic type: Bronchiolo-alveolar
adenocarcinoma

Histologic grade: Well differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/6 positive for metastasis
(Bronchopulmonary, bifurcational, aortic window
0/6)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not
specified

Additional pathologic findings: Not specified

Comments: Left- upper

Source: NCI Genomic Data Commons file eed740f8-e112-464e-88fc-a56fa094a11e (TCGA-86-8673.0E5C5229-2B1D-45D6-8FAE-02A32FB84988.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).